Somatic mutation profile of tumor specimen TCGA-AA-A01R-01A (aliquot TCGA-AA-A01R-01A-21D-A17O-10) from TCGA case TCGA-AA-A01R, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage III; Age at diagnosis: 47.3 years (17,289 days).
Specimen TCGA-AA-A01R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7348206-0264-4fd1-98f1-cbc14d7fe56b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A01R-11A (Solid Tissue Normal), aliquot TCGA-AA-A01R-11A-12D-A17O-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a3c33bf-df0b-4059-a49a-63421e9a02d9

The open-access MAF lists 2,242 somatic variants for this specimen: 1,541 protein-altering or splice-affecting, 575 silent, 126 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,339, Silent 575, Nonsense Mutation 89, Frame Shift Del 55, Intron 47, 3'UTR 37, Frame Shift Ins 25, Splice Region 20, 5'UTR 15, RNA 13, Splice Site 10, 3'Flank 8.

Variants (750 of 2,242; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 33/125 reads (26%) | hotspot (GDC flag); catalogued as rs865931787, COSV66559513; called by muse, mutect2, varscan2
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 61/217 reads (28%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | hotspot (GDC flag); catalogued as COSV61375361; called by muse, mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 134/220 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GATA2 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553770434, CM116979, COSV62004466, COSV62006245; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GCDH | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.733); catalogued as rs748275416, CM980875, COSV53368773; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HPRT1 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs387906725, CM920351, COSV100053047; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 46/176 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAK | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 98/216 reads (45%) | catalogued as rs753314164, COSV57564849; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 28/92 reads (30%) | catalogued as rs63749980, CM992183, COSV99316661; ClinVar: pathogenic; called by mutect2, varscan2
- NF2 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as rs74315499, CM930516, COSV104404659, COSV58520213; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 70/222 reads (32%) | catalogued as rs760228510, COSV56221873, COSV56224439; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 19/63 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PRF1 | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs28933376, CM030491, COSV64615387; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RHOA | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 20/88 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs1057519953, COSV69041526, COSV69042045; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SDHA | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 90/274 reads (33%) | catalogued as rs781764920, CM137000, COSV53774237; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC16A1 | c.41del p.P14Qfs*10 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC17A5 | c.349del p.Y117Mfs*17 | Frame Shift Del (DEL) | VAF 60/207 reads (29%) | catalogued as rs772039085; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- SLC2A2 | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 55/163 reads (34%) | catalogued as rs121909743, CM971382, COSV58585042; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SOX9 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 104/290 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1555629169, COSV55422898; ClinVar: likely pathogenic; called by muse, varscan2
- TCF12 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 87/143 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730880016, CM1411541, COSV51003557, COSV99032766; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886039551, CM060085, CM086981, COSV55445539, COSV55457221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TGM1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121918731, CM012196, CM065480, COSV99252672; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TRPC6 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1451194842, CM130320, COSV60252428; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 91/288 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs138438101, COSV66057789; called by muse, mutect2, varscan2
- ABCA7 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs868213967, COSV54035260; called by muse, mutect2, varscan2
- ABCB9 | c.1777G>A p.A593T (on ENST00000280560 / NM_019625.4; = p.A550T on NM_019624.3) | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1185814157, COSV54890364; called by muse, mutect2, varscan2
- ABCC3 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 88/261 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.951); catalogued as rs763074343; called by muse, mutect2
- ABCC4 | c.721A>G p.M241V | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs1351598173; called by muse, mutect2, varscan2
- ABHD16B | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs748469189, COSV99410822; called by muse, mutect2, varscan2
- ABI3BP | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 106/371 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs372669157, COSV52540615; called by muse, mutect2, varscan2
- AC013477.1 | c.2449C>T p.R817* | Nonsense Mutation (SNP) | VAF 68/382 reads (18%) | catalogued as rs766257104; called by muse, varscan2
- AC107871.1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 110/176 reads (63%) | PolyPhen possibly damaging (0.497); catalogued as rs554953385; called by muse, varscan2
- ACACB | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.371); catalogued as rs776631835; called by muse, mutect2, varscan2
- ACACB | c.6065C>A p.P2022H | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58142703; called by muse, mutect2, varscan2
- ACADS | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs754459133; called by muse, mutect2, varscan2
- ACAN | c.4338G>T p.E1446D | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.839); catalogued as rs781478525; called by muse, mutect2
- ACSS1 | c.1642C>T p.R548W | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1027957028; called by muse, mutect2, varscan2
- ACTN1 | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs781540049; called by muse, mutect2
- ADAM12 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 102/199 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776871759, COSV64112138; called by muse, mutect2, varscan2
- ADAM8 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs776195089; called by muse, mutect2, varscan2
- ADAMTS1 | c.1211-1G>T p.X404_splice | Splice Site (SNP) | VAF 17/58 reads (29%) | catalogued as COSV53169296; called by muse, mutect2, varscan2
- ADCY9 | c.2629G>A p.A877T | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as rs144986362; called by muse, mutect2, varscan2
- ADGB | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs770935625, COSV58861515; called by muse, varscan2
- ADGRB1 | c.1388G>A p.G463D | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV60101955; called by muse, mutect2, varscan2
- ADGRG3 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs376154437, COSV59650277, COSV59651601; called by muse, mutect2, varscan2
- ADGRL2 | c.983A>G p.Y328C | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54681975; called by muse, mutect2, varscan2
- ADGRL4 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.438); catalogued as rs777964454, COSV66060921; called by muse, mutect2
- ADGRV1 | c.5521C>T p.R1841C | Missense Mutation (SNP) | VAF 118/374 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); catalogued as rs367621359; called by muse, mutect2, varscan2
- ADH1C | c.634T>A p.C212S | Missense Mutation (SNP) | VAF 101/304 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101565200; called by muse, mutect2, varscan2
- ADNP | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 135/448 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1176208415; called by muse, varscan2
- ADRA1A | c.328T>C p.C110R | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167310025, COSV52371408; called by muse, mutect2, varscan2
- ADRA2A | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.54); PolyPhen benign (0.438); catalogued as COSV99701764; called by muse, mutect2, varscan2
- ADRB1 | c.1058T>G p.L353R | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as COSV100992305; called by muse, mutect2, varscan2
- AGA | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572348048, COSV99219586; called by muse, mutect2, varscan2
- AGRN | c.5833G>A p.V1945M | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.47); catalogued as rs145079121; called by muse, mutect2, varscan2
- AHNAK | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.371); catalogued as rs781648735, COSV57204309; called by muse, mutect2, varscan2
- AIFM2 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs774916584, COSV57158674; called by muse, mutect2, varscan2
- AJM1 | c.1583A>C p.Y528S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99915830; called by muse, mutect2, varscan2
- AJM1 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.815); catalogued as COSV56034596; called by muse, mutect2, varscan2
- AKAP12 | c.3479del p.P1160Lfs*18 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | catalogued as COSV53580835; called by mutect2, pindel, varscan2
- AKAP3 | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as rs749738318, COSV57414538; called by muse, mutect2, varscan2
- AKR1B10 | c.730dup p.T244Nfs*29 | Frame Shift Ins (INS) | VAF 35/99 reads (35%) | catalogued as rs1333065534; called by mutect2, varscan2
- AKR1E2 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as rs748631440, COSV53629928; called by muse, mutect2, varscan2
- ALDH16A1 | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs768690823, COSV53193518; called by muse, mutect2, varscan2
- ALDH18A1 | c.2293C>T p.R765* | Nonsense Mutation (SNP) | VAF 48/217 reads (22%) | catalogued as rs1462559161; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ALDH1B1 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs755939166; called by muse, mutect2, varscan2
- ALDH1L1 | c.2608G>A p.A870T | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as rs200290145, COSV56411228; called by muse, mutect2, varscan2
- ALOX15B | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as COSV66480104; called by muse, mutect2, varscan2
- ALPK1 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749235785, COSV51587806; called by muse, mutect2, varscan2
- ALS2CL | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs753736240, COSV59672158; called by muse, mutect2, varscan2
- AMMECR1L | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 33/97 reads (34%) | catalogued as COSV55760701, COSV55761571; called by muse, mutect2, varscan2
- AMZ1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs771028590, COSV56688799; called by muse, mutect2, varscan2
- ANK3 | c.4304C>A p.T1435N (on ENST00000280772 / NM_001320874.2; = p.T569N on NM_001149.3) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55074857; called by muse, mutect2, varscan2
- ANK3 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as rs773759951, COSV55074866; called by muse, mutect2, varscan2
- ANKIB1 | c.452A>G p.Y151C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs781353771; called by muse, mutect2, varscan2
- ANKMY2 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | catalogued as rs1478992649; called by muse, mutect2, varscan2
- ANKRD13B | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as rs1405395467, COSV67474322; called by muse, mutect2, varscan2
- AOC2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs145007333; called by muse, mutect2, varscan2
- AP1M1 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1228874814, COSV52227175; called by muse, mutect2, varscan2
- APBA2 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs780215700, COSV67104207; called by muse, mutect2, varscan2
- APOBEC3C | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as rs1569049068, COSV63865647; called by muse, mutect2, varscan2
- APOBEC3C | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs1411054991; called by muse, mutect2, varscan2
- APOBR | c.2427G>T p.E809D (on ENST00000431282; = p.E818D on NM_018690.4) | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); catalogued as COSV100112780; called by muse, mutect2
- APOH | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.125); catalogued as rs763687723; called by muse, mutect2, varscan2
- AQP7 | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs541770524; called by muse, mutect2, varscan2
- AQP7 | c.700dup p.R234Pfs*61 | Frame Shift Ins (INS) | VAF 18/48 reads (38%) | catalogued as rs3215969; called by mutect2, varscan2
- ARAP3 | c.3085C>T p.R1029C | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs150284423; called by muse, mutect2, varscan2
- ARHGAP12 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs1195703426; called by muse, mutect2, varscan2
- ARHGAP25 | c.1876A>G p.K626E (on ENST00000409202 / NM_001007231.3; = p.K618E on NM_014882.3) | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs752213184; called by muse, mutect2, varscan2
- ARHGAP31 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1260603822, COSV51800770; called by muse, mutect2, varscan2
- ARHGAP5 | c.2676del p.F892Lfs*9 | Frame Shift Del (DEL) | VAF 37/143 reads (26%) | catalogued as rs781483073; called by mutect2, pindel, varscan2
- ARHGEF18 | c.797G>A p.R266Q (on ENST00000359920 / NM_001130955.2; = p.R162Q on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.107); catalogued as rs146605267; called by muse, mutect2, varscan2
- ARHGEF26 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV62847241; called by muse, mutect2, varscan2
- ARHGEF5 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 88/298 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs751529421, COSV99283093; called by muse, mutect2, varscan2
- ARID4A | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs148135007; called by muse, mutect2, varscan2
- ARL4A | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 18/413 reads (4%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.769); catalogued as COSV100775951; called by muse, mutect2
- ASB13 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764527518, COSV100731350; called by muse, mutect2, varscan2
- ASH1L | c.8537G>A p.R2846H (on ENST00000368346 / NM_001366177.2; = p.R2841H on NM_018489.3) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs779448272, COSV64208479, COSV64209040; called by muse, mutect2, varscan2
- ASPM | c.6796G>A p.A2266T | Missense Mutation (SNP) | VAF 81/176 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200800956; called by muse, mutect2, varscan2
- ASPSCR1 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.602); catalogued as rs984947339, COSV100144807; called by muse, mutect2, varscan2
- ASXL3 | c.5652G>A p.M1884I | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52475288; called by muse, mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 27/115 reads (23%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATF7IP | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs773514506; called by muse, mutect2, varscan2
- ATG16L2 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369947367; called by muse, mutect2, varscan2
- ATG2A | c.1925C>T p.T642M | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.818); catalogued as rs758825597; called by muse, varscan2
- ATIC | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as rs774939270, COSV52693910; called by muse, mutect2, varscan2
- ATM | c.8615A>G p.H2872R | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53757274; called by muse, mutect2, varscan2
- ATP11A | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs769716430, COSV52120087; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP2A3 | c.2414C>T p.T805M | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as rs751615148, COSV99988914; called by muse, varscan2
- ATP2B1 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs368317255; called by muse, mutect2, varscan2
- ATP9A | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539931418, COSV58763991; called by muse, mutect2, varscan2
- ATP9B | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 154/453 reads (34%) | catalogued as rs376702405; called by muse, mutect2, varscan2
- ATP9B | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs745961288, COSV56951624; called by muse, mutect2, varscan2
- ATRNL1 | c.576del p.F192Lfs*8 | Frame Shift Del (DEL) | VAF 116/224 reads (52%) | catalogued as rs1554873914; called by mutect2, varscan2
- AVPI1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs554930916; called by muse, mutect2, varscan2
- AVPR1B | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs369649163; called by muse, mutect2, varscan2
- B3GNT8 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as rs768303766; called by muse, mutect2, varscan2
- B4GALT3 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as COSV100157745; called by muse, mutect2, varscan2
- B4GALT6 | c.646A>G p.M216V | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as rs749390292; called by muse, varscan2
- BARHL2 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as rs1355901658, COSV64982206; called by muse, mutect2, varscan2
- BCAT2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as rs549092161; called by muse, mutect2, varscan2
- BCL7A | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 84/252 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs749055080, COSV55847482; called by muse, mutect2, varscan2
- BCL9 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV52343167, COSV52347744; called by muse, mutect2, varscan2
- BCL9L | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs368375563; called by muse, mutect2, varscan2
- BCL9L | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs749087122; called by muse, varscan2
- BEGAIN | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1306583469, COSV62068416; called by muse, mutect2, varscan2
- BEND3 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs782522231, COSV100944590, COSV100944620; called by muse, mutect2, varscan2
- BEST4 | c.482-1G>T p.X161_splice | Splice Site (SNP) | VAF 24/78 reads (31%) | catalogued as COSV100944038; called by muse, mutect2, varscan2
- BICRA | c.2810dup p.P938Tfs*127 | Frame Shift Ins (INS) | VAF 33/172 reads (19%) | catalogued as rs755506199; called by mutect2, varscan2
- BICRA | c.4001C>T p.P1334L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs761447479, COSV101194254, COSV101194436; called by muse, mutect2, varscan2
- BIN1 | c.1412C>T p.A471V (on ENST00000316724 / NM_001320642.1; = p.A332V on NM_004305.4) | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs746346952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs778387106; called by muse, mutect2, varscan2
- BLVRB | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99648033; called by muse, mutect2, varscan2
- BMP1 | c.2914C>T p.R972* | Nonsense Mutation (SNP) | VAF 41/137 reads (30%) | catalogued as rs773343328; called by muse, mutect2, varscan2
- BMP2K | c.2888C>T p.T963M | Missense Mutation (SNP) | VAF 77/249 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.826); catalogued as rs370861712; called by muse, mutect2, varscan2
- BNIPL | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs371326091; called by muse, mutect2, varscan2
- BORCS6 | c.938T>C p.M313T | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as rs766704278; called by muse, mutect2, varscan2
- BRD8 | c.1535C>A p.P512H (on ENST00000254900 / NM_139199.2; = p.P585H on NM_006696.4) | Missense Mutation (SNP) | VAF 35/518 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.471); catalogued as COSV99136806, COSV99137358; called by muse, mutect2
- BSN | c.3034C>T p.R1012C | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374765989; called by muse, mutect2, varscan2
- BTN3A2 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 297/450 reads (66%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs376441641; called by muse, mutect2, varscan2
- C10orf88 | c.401del p.N134Ifs*2 | Frame Shift Del (DEL) | VAF 106/266 reads (40%) | catalogued as rs751388819; called by mutect2, varscan2
- C11orf87 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as rs1205783414, COSV59357381; called by muse, mutect2, varscan2
- C12orf71 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.133); catalogued as rs201692205; called by muse, mutect2, varscan2
- C16orf96 | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868035054, COSV71472349; called by muse, mutect2, varscan2
- C1orf159 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as rs747421436, COSV53880621; called by muse, mutect2, varscan2
- C2CD2 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.125); catalogued as rs747708713; called by muse, mutect2, varscan2
- C2orf78 | c.2269A>G p.T757A | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as rs1454436024; called by muse, mutect2, varscan2
- C7 | c.2489T>C p.I830T | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV100496371; called by muse, mutect2
- C8orf34 | c.341A>C p.K114T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61391144; called by muse, mutect2, varscan2
- C9orf152 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs780345431; called by muse, mutect2, varscan2
- CABIN1 | c.3835G>A p.D1279N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.549); catalogued as rs767920054, COSV54088118; called by muse, mutect2, varscan2
- CACNA1E | c.6148C>T p.R2050C (on ENST00000367573 / NM_001205293.3; = p.R2007C on NM_000721.4) | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs769307233, COSV62384798; called by muse, mutect2, varscan2
- CACNA1G | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1392140625, COSV61735126; called by muse, mutect2, varscan2
- CACNB3 | c.744G>A p.A248= | Splice Region (SNP) | VAF 15/39 reads (38%) | catalogued as rs778175847, COSV99975175; called by muse, varscan2
- CADPS | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 107/294 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs760015455, COSV51900880; called by muse, mutect2, varscan2
- CAPN5 | c.1772C>T p.S591L (on ENST00000456580; = p.S551L on NM_004055.5) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs782766470, COSV53688617; called by muse, mutect2, varscan2
- CARD14 | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs577478029, COSV60122251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARMIL3 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 41/116 reads (35%) | catalogued as rs758789412, COSV57725926; called by muse, mutect2, varscan2
- CASZ1 | c.4312G>A p.D1438N | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs375316064; called by muse, mutect2, varscan2
- CBX2 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1555830311; called by muse, mutect2, varscan2
- CBY2 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100137788; called by muse, mutect2, varscan2
- CC2D2A | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs772016081, COSV67504953; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC144A | c.3799G>A p.D1267N | Missense Mutation (SNP) | VAF 181/1159 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs780526699, COSV100138644; called by muse, mutect2, varscan2
- CCDC154 | c.1825C>T p.R609W | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs765670349, COSV101209704; called by muse, mutect2, varscan2
- CCDC154 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as rs1016490294; called by muse, mutect2, varscan2
- CCDC157 | c.248+8C>T | Splice Region (SNP) | VAF 35/81 reads (43%) | catalogued as rs377414522; called by muse, mutect2, varscan2
- CCDC168 | c.16747C>A p.P5583T | Missense Mutation (SNP) | VAF 145/435 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs1244494808; called by muse, mutect2, varscan2
- CCDC180 | c.4916A>G p.Q1639R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.14); catalogued as COSV63829154; called by muse, mutect2, varscan2
- CCDC30 | c.1984C>T p.R662* (on ENST00000340612; = p.R619* on NM_001080850.3) | Nonsense Mutation (SNP) | VAF 29/90 reads (32%) | catalogued as rs944852189, COSV100501175; called by muse, mutect2, varscan2
- CCDC61 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV50517303; called by muse, mutect2, varscan2
- CCDC80 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1216753978, COSV52819921; called by muse, mutect2, varscan2
- CCDC88C | c.3763C>T p.R1255W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs1226329586, COSV66240592; called by muse, mutect2, varscan2
- CCDC88C | c.2650G>A p.G884S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs185802741; called by muse, mutect2, varscan2
- CCM2L | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as rs1441651739, COSV52951919; called by muse, mutect2, varscan2
- CD1C | c.60C>T p.D20= | Splice Region (SNP) | VAF 36/130 reads (28%) | catalogued as rs539975387, COSV63806226; called by muse, mutect2, varscan2
- CD247 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs148513413, COSV62977733; called by muse, varscan2
- CD9 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs146304211; called by muse, mutect2, varscan2
- CDH23 | c.8310C>T p.A2770= | Splice Region (SNP) | VAF 23/103 reads (22%) | catalogued as rs749582906, COSV99823014; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH26 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 77/223 reads (35%) | catalogued as rs766848205, COSV54844761; called by muse, mutect2, varscan2
- CDK19 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1219070923, COSV100098258, COSV60454042; called by muse, mutect2, varscan2
- CDKN2C | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.052); catalogued as rs746646631; called by muse, mutect2, varscan2
- CDR2L | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.462); catalogued as rs1216064642; called by muse, mutect2, varscan2
- CELSR3 | c.6484C>T p.R2162W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542163838, COSV99375106; called by muse, mutect2, varscan2
- CELSR3 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs531319649; called by muse, mutect2, varscan2
- CEMIP2 | c.3788C>T p.T1263M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs751646051; called by muse, mutect2, varscan2
- CEP164 | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs541217768, COSV54040575; called by muse, mutect2, varscan2
- CEP44 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 151/318 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.117); catalogued as rs768900374; called by muse, mutect2
- CEP85L | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs769405047; called by muse, mutect2, varscan2
- CFAP69 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 93/326 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV60186102; called by muse, mutect2, varscan2
- CGN | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765530896; called by muse, mutect2, varscan2
- CHRNA4 | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as rs121912269; ClinVar: not provided; called by muse, mutect2, varscan2
- CHST1 | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57321811; called by muse, mutect2, varscan2
- CHST1 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1281857217, COSV57323648; called by muse, mutect2, varscan2
- CIC | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs376580917; called by muse, mutect2, varscan2
- CISH | c.20+7G>A | Splice Region (SNP) | VAF 22/67 reads (33%) | catalogued as rs1157158333; called by muse, mutect2, varscan2
- CKM | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1430253523, COSV99488493; called by muse, mutect2, varscan2
- CLEC18C | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 264/1202 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs775805027, COSV58500344; called by muse, mutect2, varscan2
- CLMP | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs139133124; called by muse, mutect2, varscan2
- CLSTN3 | c.1747G>A p.V583M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as rs977884846, COSV56939326; called by muse, mutect2, varscan2
- CLTC | c.2683C>T p.R895C | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs1449246482, COSV52251598; called by muse, mutect2, varscan2
- CLU | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.195); catalogued as rs146625005; called by muse, mutect2, varscan2
- CLYBL | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV59226920; called by muse, mutect2, varscan2
- CMYA5 | c.6018G>T p.E2006D | Missense Mutation (SNP) | VAF 102/353 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.378); catalogued as COSV71408588; called by muse, mutect2, varscan2
- CNDP2 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs771837186; called by muse, mutect2, varscan2
- CNIH1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs1206272751, COSV53594572; called by muse, mutect2, varscan2
- CNOT6L | c.917C>T p.A306V (on ENST00000504123 / NM_001286790.2; = p.A301V on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1481358623, COSV53698148; called by muse, mutect2, varscan2
- CNTN3 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1418842277, COSV55164966, COSV55169547; called by muse, mutect2, varscan2
- CNTNAP2 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 96/298 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.095); catalogued as rs1064794785, COSV62183982, COSV62208424; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1448342066, COSV70491153; called by muse, mutect2, varscan2
- COL18A1 | c.3121C>T p.R1041* (on ENST00000359759 / NM_130444.3; = p.R806* on NM_030582.4) | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs753935209, COSV60593826; called by muse, mutect2, varscan2
- COL24A1 | c.1843G>T p.G615C | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65305104, COSV65312329; called by muse, mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 36/133 reads (27%) | catalogued as rs760493024; called by mutect2, varscan2
- COL5A1 | c.2015G>T p.R672M | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs1344264716; called by muse, mutect2, varscan2
- COL5A1 | c.4384G>A p.G1462S | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776108281; called by muse, mutect2, varscan2
- COL6A2 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as rs371383704, COSV100153416; called by muse, mutect2, varscan2
- COL6A3 | c.7162C>T p.P2388S | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs764688620; called by muse, mutect2, varscan2
- COLGALT1 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1462939279; called by muse, mutect2, varscan2
- COMP | c.1168G>A p.V390I | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs151050419; called by muse, mutect2, varscan2
- COPS7B | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs756302127, COSV63115537; called by muse, mutect2, varscan2
- CPSF1 | c.1951G>A p.V651M | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as rs782245666; called by muse, mutect2, varscan2
- CPT1B | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760342156; called by muse, mutect2, varscan2
- CRHR2 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as rs764886717, COSV59267348; called by muse, mutect2, varscan2
- CRMP1 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs1417061818; called by muse, mutect2, varscan2
- CRTC2 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 103/334 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.548); catalogued as rs749680802, COSV100339239, COSV57841846; called by muse, varscan2
- CRTC2 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs143226168; called by muse, mutect2, varscan2
- CSDE1 | c.1522C>T p.R508* (on ENST00000358528 / NM_001007553.3; = p.R477* on NM_007158.6) | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as rs750855257, COSV54747303; called by muse, mutect2, varscan2
- CSRNP3 | c.1149G>T p.E383D | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100084877; called by muse, mutect2, varscan2
- CTAGE4 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 23/135 reads (17%) | catalogued as rs1232494853, COSV100967782; called by mutect2, varscan2
- CTBP1 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs773926313, COSV52074642; called by muse, mutect2, varscan2
- CTCFL | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54772324; called by muse, mutect2, varscan2
- CTDP1 | c.2113G>A p.V705M | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs372703325, COSV99311037; called by muse, mutect2, varscan2
- CTNNA1 | c.2257G>T p.G753* | Nonsense Mutation (SNP) | VAF 54/177 reads (31%) | catalogued as COSV57074495; called by muse, mutect2, varscan2
- CTSG | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs865944750, COSV53536477; called by muse, mutect2, varscan2
- CYP27C1 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV58866205; called by muse, mutect2, varscan2
- CYP4F22 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs144569785; called by muse, mutect2, varscan2
- DAB1 | c.1686G>T p.Q562H (on ENST00000371231; = p.Q529H on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.825); catalogued as COSV100976738, COSV64696356; called by muse, mutect2, varscan2
- DAPK1 | c.2266G>A p.V756M | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as rs1358422658; called by muse, mutect2, varscan2
- DAPK1 | c.4227G>T p.E1409D | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs889544516; called by muse, mutect2, varscan2
- DBH | c.26G>A p.S9N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1191237522, COSV99707986; called by muse, mutect2, varscan2
- DCAF12L2 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100758767; called by muse, mutect2, varscan2
- DCAF15 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV54329900; called by muse, mutect2, varscan2
- DCAF4L1 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 34/126 reads (27%) | catalogued as rs547538687; called by muse, mutect2, varscan2
- DCAF4L2 | c.818T>C p.V273A | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV60478694; called by muse, mutect2, varscan2
- DCLK3 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs181512442; called by muse, mutect2, varscan2
- DDI1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs766051930, COSV56384748; called by muse, mutect2, varscan2
- DDX3Y | c.151+4C>T | Splice Region (SNP) | VAF 39/129 reads (30%) | catalogued as rs1224821716; called by muse, mutect2, varscan2
- DDX56 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs62459150; called by muse, mutect2, varscan2
- DENND2C | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs199921408, COSV67923808; called by muse, mutect2, varscan2
- DENND4B | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs764285501, COSV63409338; called by muse, mutect2, varscan2
- DIDO1 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 124/364 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV99827263; called by muse, mutect2, varscan2
- DIP2A | c.2905G>A p.G969R | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757164188, COSV59484311; called by muse, mutect2, varscan2
- DIS3L2 | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV56051557; called by muse, mutect2, varscan2
- DLC1 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs545557528; called by muse, mutect2, varscan2
- DNAAF1 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs536922836, COSV57576801; called by muse, mutect2, varscan2
- DNAH1 | c.2300A>G p.K767R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs751120287, COSV70233924; called by muse, mutect2, varscan2
- DNAH11 | c.2275-1G>A p.X759_splice | Splice Site (SNP) | VAF 28/70 reads (40%) | catalogued as CS1110426, COSV100180241; called by muse, varscan2
- DNAH3 | c.10010C>T p.T3337M | Missense Mutation (SNP) | VAF 85/257 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs530510705, COSV54505745; called by muse, mutect2, varscan2
- DNAJC11 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 59/185 reads (32%) | catalogued as rs267598695, COSV53784590; called by muse, mutect2, varscan2
- DNHD1 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs148449070; called by muse, mutect2, varscan2
- DNHD1 | c.5393G>A p.R1798H | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as rs377544172; called by muse, mutect2, varscan2
- DOC2A | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1346621524, COSV58750681; called by muse, mutect2, varscan2
- DOP1A | c.6833C>T p.T2278M | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs754031065; called by muse, mutect2, varscan2
- DPCD | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as rs773833827; called by muse, mutect2, varscan2
- DPH1 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs753008362, COSV53984401; called by muse, mutect2, varscan2
- DPP10 | c.1142G>A p.G381D | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV59711718; called by muse, mutect2, varscan2
- DRAM2 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1363827522; called by muse, mutect2, varscan2
- DROSHA | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 79/237 reads (33%) | catalogued as rs762001670, COSV60773292; called by muse, mutect2, varscan2
- DSG1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); catalogued as rs770916767, COSV57134860; called by muse, mutect2, varscan2
- DST | c.7708G>A p.D2570N | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); catalogued as rs144013177; called by muse, mutect2, varscan2
- DUS3L | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs763571268, COSV57831190; called by muse, mutect2, varscan2
- DYNC1H1 | c.12191C>T p.T4064M | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs750249796, COSV64135613; called by muse, mutect2, varscan2
- DYNC1H1 | c.13912C>T p.R4638W | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200224597, COSV64142862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2H1 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs757134411, COSV62094130; called by muse, mutect2, varscan2
- DYNC2H1 | c.8060T>C p.L2687P | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1386216588; called by muse, mutect2, varscan2
- DYRK3 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200378422; called by muse, mutect2, varscan2
- DYSF | c.2801C>T p.P934L | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150717638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DZIP3 | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs149807869; called by muse, varscan2
- E4F1 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1322258766; called by muse, mutect2, varscan2
- ECSIT | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs774065936, COSV52938474; called by muse, mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 26/100 reads (26%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EEF1AKMT4-ECE2 | c.2591G>T p.R864L | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV62570028; called by muse, mutect2, varscan2
- EFTUD2 | c.2791C>T p.R931W | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755757989, COSV53656027; called by muse, mutect2, varscan2
- EGFR | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs552062864, COSV51802220; called by muse, mutect2, varscan2
- EHD3 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs183394828; called by muse, mutect2, varscan2
- ELK1 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.299); catalogued as rs774244991, COSV55954640; called by muse, mutect2, varscan2
- ELL | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 248/692 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs759014608, COSV53211646; called by muse, varscan2
- ELOA2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.212); catalogued as rs1436684834; called by muse, mutect2
- EML1 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as rs749465112, COSV51747708; called by muse, mutect2, varscan2
- EP400 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs566501800; called by muse, mutect2, varscan2
- EPB41L4B | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746270390, COSV65798195; called by muse, mutect2, varscan2
- EPG5 | c.4361G>A p.R1454H | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as rs766875773, COSV56348725; called by muse, mutect2, varscan2
- EPHA1 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV51974539; called by muse, mutect2, varscan2
- EPHB1 | c.2764G>A p.A922T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs373797543, COSV67655662, COSV67667897; called by muse, mutect2, varscan2
- EPHX2 | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV66844896; called by muse, mutect2, varscan2
- EPPK1 | c.4939C>T p.R1647C | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs375118468; called by muse, mutect2, varscan2
- EPPK1 | c.1366G>A p.V456I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs782354575; called by muse, mutect2, varscan2
- EPS8L1 | c.919C>T p.R307W (on ENST00000201647 / NM_133180.3; = p.R180W on NM_017729.3) | Missense Mutation (SNP) | VAF 86/228 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52384995; called by muse, mutect2, varscan2
- ESF1 | c.512del p.N171Tfs*18 | Frame Shift Del (DEL) | VAF 50/161 reads (31%) | catalogued as rs745713173; called by mutect2, varscan2
- ESYT2 | c.2430C>T p.C810= (on ENST00000613624; = p.C734= on NM_020728.3) | Splice Region (SNP) | VAF 30/86 reads (35%) | catalogued as rs1416429312; called by muse, mutect2, varscan2
- EVI5L | c.2323G>T p.G775C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); catalogued as rs1490741113, COSV99563451; called by muse, mutect2, varscan2
- EXOC2 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs373080488; called by muse, mutect2, varscan2
- EXOC3L2 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771973379, COSV99374587; called by muse, mutect2, varscan2
- EXPH5 | c.3756A>G p.I1252M | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs761525773; called by muse, mutect2, varscan2
- EXTL3 | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173785722; called by muse, mutect2, varscan2
- FAIM2 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773139598; called by muse, mutect2, varscan2
- FAM124A | c.112G>A p.V38I (on ENST00000322475 / NM_001242312.2; = p.V74I on NM_145019.4) | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as rs1385627594, COSV99696256; called by muse, mutect2, varscan2
- FAM135B | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as rs375948638; called by muse, mutect2, varscan2
- FAM13C | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs200555371; called by muse, mutect2, varscan2
- FAM151B | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs527461710, COSV56473365; called by muse, mutect2, varscan2
- FAM184B | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1422761354; called by muse, mutect2, varscan2
- FAM186A | c.4235C>T p.T1412I | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs767988960; called by muse, mutect2
- FARSA | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs368745199; called by muse, mutect2, varscan2
- FAT1 | c.11318G>A p.R3773H | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs766902640, COSV71676390; called by muse, mutect2, varscan2
- FAT2 | c.7709C>T p.T2570M | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs560174924; called by muse, mutect2, varscan2
- FAT4 | c.10205A>G p.D3402G | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58710872; called by muse, mutect2, varscan2
- FBN3 | c.8165G>T p.R2722L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs545168335; called by muse, mutect2, varscan2
- FBRSL1 | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1474642560; called by muse, mutect2, varscan2
- FBXL14 | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.129); catalogued as rs1172292333; called by muse, mutect2, varscan2
- FBXW11 | c.1389-2A>G p.X463_splice | Splice Site (SNP) | VAF 26/60 reads (43%) | catalogued as COSV99441242; called by muse, mutect2, varscan2
- FCGBP | c.6655G>A p.A2219T | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.137); catalogued as COSV99664632; called by muse, mutect2, varscan2
- FCHO1 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs144793428; called by muse, mutect2, varscan2
- FCHO1 | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs151277101; called by muse, mutect2, varscan2
- FCHSD1 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750065628, COSV51838097; called by muse, mutect2, varscan2
- FCRL4 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as rs142198646; called by muse, mutect2, varscan2
- FECH | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs770820411, COSV50493747; called by muse, mutect2, varscan2
- FECH | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs746310270, CM131417; called by muse, mutect2, varscan2
- FER1L5 | c.4927C>T p.R1643W (on ENST00000623019; = p.R1616W on NM_001293083.2) | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.549); catalogued as rs368260119; called by muse, mutect2, varscan2
- FEZF1 | c.191C>A p.S64Y | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as COSV58658503; called by muse, mutect2, varscan2
- FGF8 | c.292G>A p.G98S (on ENST00000344255 / NM_033164.4; = p.G80S on NM_006119.6) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100199402, COSV60142950; called by muse, mutect2, varscan2
- FGFR3 | c.*1085G>A | Splice Region (SNP) | VAF 22/63 reads (35%) | catalogued as rs1426369141, COSV53406788; called by muse, mutect2, varscan2
- FH | c.953A>G p.H318R | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as rs755449276, CM061769; called by muse, mutect2, varscan2
- FHAD1 | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs764165573; called by muse, mutect2, varscan2
- FHOD1 | c.2512G>A p.G838S | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1397835458; called by muse, mutect2, varscan2
- FHOD1 | c.1270A>G p.I424V | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs765946969; called by muse, mutect2, varscan2
- FIZ1 | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs759126429; called by muse, varscan2
- FLNB | c.6310C>T p.R2104W | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs751795794; called by muse, mutect2, varscan2
- FLYWCH1 | c.335A>G p.Q112R (on ENST00000253928 / NM_001308068.2; = p.Q111R on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs1307553140; called by muse, mutect2, varscan2
- FNDC3B | c.3165dup p.T1056Hfs*16 | Frame Shift Ins (INS) | VAF 24/84 reads (29%) | catalogued as rs769012096; called by mutect2, varscan2
- FOXK1 | c.1858C>T p.R620W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs762122739, COSV100195831, COSV100196127; called by muse, mutect2, varscan2
- FOXO3 | c.1754A>C p.D585A | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.13); catalogued as COSV100670098; called by muse, mutect2, varscan2
- FOXS1 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs370481154; called by muse, mutect2, varscan2
- FPR3 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 158/439 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.258); catalogued as rs764805147, COSV59330276; called by muse, mutect2, varscan2
- FRYL | c.6122G>A p.R2041Q | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs764312788, COSV51940848, COSV51952315; called by muse, mutect2, varscan2
- FSIP2 | c.19584del p.K6528Nfs*5 | Frame Shift Del (DEL) | VAF 64/230 reads (28%) | catalogued as rs781034813; called by mutect2, pindel, varscan2
- FSTL4 | c.329A>G p.N110S | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54768336, COSV54781751; called by muse, mutect2, varscan2
- FUT5 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 78/253 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs781634935, COSV99398802; called by muse, mutect2, varscan2
- FXYD5 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs200435409, COSV100732733, COSV61569100; called by muse, mutect2, varscan2
- FZD10 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.172); catalogued as COSV57471932; called by muse, mutect2, varscan2
- G6PC3 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs140785361; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAL3ST2 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769648241, COSV51951004; called by muse, mutect2, varscan2
- GAL3ST4 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs766246233, COSV57587649; called by muse, mutect2, varscan2
- GAS2L3 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764425648; called by muse, mutect2, varscan2
- GATAD2A | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.107); catalogued as rs770792058; called by muse, mutect2, varscan2
- GDPD2 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs910630290, COSV65533888; called by muse, mutect2, varscan2
- GIMAP8 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.619); catalogued as rs143529569, COSV56234548; called by muse, mutect2, varscan2
- GJA10 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as rs540684772; called by muse, mutect2, varscan2
- GJB4 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs370587030; called by muse, mutect2, varscan2
- GLIS2 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1287524266, COSV52109238; called by muse, mutect2, varscan2
- GLRA4 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 63/95 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755433619, COSV65456618; called by muse, mutect2, varscan2
- GNRHR | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs200026876, COSV99892401; called by muse, mutect2, varscan2
- GOT1L1 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV56874980; called by muse, mutect2, varscan2
- GPC3 | c.1130A>G p.H377R | Missense Mutation (SNP) | VAF 161/250 reads (64%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs1060502172; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPCPD1 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as rs748581132, COSV66831688; called by muse, mutect2, varscan2
- GPHN | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59489066; called by muse, mutect2, varscan2
- GPR1 | c.790C>A p.L264M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV101329849; called by muse, mutect2, varscan2
- GPR158 | c.3222G>A p.W1074* | Nonsense Mutation (SNP) | VAF 41/94 reads (44%) | catalogued as COSV100894402; called by muse, mutect2, varscan2
- GPR180 | c.1193A>G p.Q398R | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as rs754117607; called by muse, mutect2, varscan2
- GPR45 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 86/243 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs750639584, COSV99306623; called by muse, mutect2, varscan2
- GPRC5A | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs775011273, COSV50007301; called by muse, mutect2, varscan2
- GPS1 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1397851548; called by muse, mutect2, varscan2
- GRAMD1C | c.459+2T>C p.X153_splice | Splice Site (SNP) | VAF 85/264 reads (32%) | catalogued as rs769168097, COSV63984776; called by muse, mutect2, varscan2
- GREB1L | c.2510G>A p.R837H | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); catalogued as rs1297427942, COSV52565726; called by muse, mutect2, varscan2
- GRID2 | c.2558C>T p.T853M | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.579); catalogued as rs755122604, COSV56170780; called by muse, mutect2, varscan2
- GRIN2A | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.75); catalogued as rs747214620, COSV58050698; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIP2 | c.2248G>A p.V750I (on ENST00000619221; = p.V653I on NM_001080423.4) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs746354259, COSV56122204; called by muse, mutect2, varscan2
- GRK6 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1479264805; called by muse, mutect2, varscan2
- H1-1 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 359/527 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV55118693; called by muse, mutect2, varscan2
- HAAO | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.299); catalogued as rs759103777, COSV54313194; called by muse, mutect2, varscan2
- HAX1 | c.196A>G p.S66G | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs769438062, COSV55168102; called by muse, mutect2, varscan2
- HCN4 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 73/122 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs143339036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDAC5 | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776063265, COSV52242466; called by muse, mutect2, varscan2
- HDAC7 | c.71G>A p.R24H (on ENST00000427332; = p.R63H on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/236 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371297447; called by muse, mutect2, varscan2
- HDLBP | c.3410G>A p.R1137H | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100189749; called by muse, mutect2, varscan2
- HEATR4 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs755190660; called by muse, mutect2, varscan2
- HECTD3 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs774871050, COSV55801297; called by muse, mutect2, varscan2
- HELZ | c.2822C>T p.A941V | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs752069712; called by muse, mutect2, varscan2
- HELZ2 | c.2275G>A p.V759M (on ENST00000467148 / NM_001037335.2; = p.V190M on NM_033405.3) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as rs769167544, COSV64409184; called by muse, mutect2, varscan2
- HGH1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 138/383 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs991046047; called by muse, mutect2, varscan2
- HIP1R | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs368392512; called by muse, mutect2, varscan2
- HK3 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.5); catalogued as rs1322178837; called by muse, mutect2, varscan2
- HMGXB3 | c.2324G>A p.R775Q (on ENST00000613459; = p.R529Q on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.439); catalogued as rs565914929, COSV101490829; called by muse, mutect2, varscan2
- HMX2 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752047204; called by muse, mutect2, varscan2
- HNF1B | c.1089_1091del p.S364del | In Frame Del (DEL) | VAF 20/82 reads (24%) | catalogued as rs1391035164; called by pindel, varscan2
- HNRNPK | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100699069; called by muse, mutect2, varscan2
- HP1BP3 | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.416); catalogued as rs968930016, COSV100391550, COSV56565253; called by muse, mutect2, varscan2
- HPCA | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs774794783, COSV100992215, COSV65102640; called by muse, mutect2, varscan2
- HR | c.3437C>T p.S1146F | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV57194091; called by muse, mutect2, varscan2
- HS1BP3 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs766823009; called by muse, mutect2
- HS3ST4 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs753467285, COSV58805150; called by muse, mutect2, varscan2
- HSD17B2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.243); catalogued as rs373965697; called by muse, mutect2, varscan2
- HSPA12A | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); catalogued as rs781852527; called by muse, mutect2, varscan2
- HSPA9 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 84/287 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs776644009, COSV51864321; called by muse, mutect2, varscan2
- HSPB11 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs746875573, COSV52040405; called by muse, varscan2
- HTR1B | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as rs200726002, COSV100885493, COSV64052020; called by muse, mutect2, varscan2
- HTR3A | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.16); catalogued as rs143359617; called by muse, mutect2, varscan2
- ICE1 | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV56830056; called by muse, mutect2, varscan2
- IFT172 | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs201921339; called by muse, mutect2, varscan2
- IGF2BP1 | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1567828704; called by muse, mutect2, varscan2
- IGF2R | c.6673G>A p.V2225M | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as rs752921831; called by muse, mutect2, varscan2
- IGHMBP2 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751421003, COSV54825896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV3-33 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 61/292 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.246); catalogued as rs371531100; called by muse, mutect2, varscan2
- IGSF10 | c.6967G>A p.V2323M | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.438); catalogued as rs774302298, COSV56373184; called by muse, mutect2, varscan2
- IGSF9B | c.1088G>A p.G363D | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1368859731, COSV58071272; called by muse, mutect2, varscan2
- IKBKE | c.162G>T p.R54S | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100898356; called by muse, mutect2, varscan2
- IKBKE | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 82/368 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs782549877, COSV65624211; called by muse, mutect2, varscan2
- IL11RA | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs538108515; called by muse, mutect2, varscan2
- IL16 | c.833T>C p.L278P | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57267071; called by muse, mutect2, varscan2
- IL31 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs763913368; called by muse, mutect2, varscan2
- INCENP | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs535973051, COSV53914306; called by muse, mutect2, varscan2
- INF2 | c.2878G>T p.V960F | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV53035337; called by muse, mutect2, varscan2
- ING5 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 172/495 reads (35%) | catalogued as rs758519998; called by muse, mutect2, varscan2
- INHBA | c.1184A>G p.K395R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.094); catalogued as rs771243659, COSV99638665; called by muse, mutect2, varscan2
- INSYN1 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.839); catalogued as rs565532541; called by muse, mutect2, varscan2
- INTS7 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.661); catalogued as rs780657722; called by muse, mutect2, varscan2
- INVS | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as rs757534991; called by muse, mutect2, varscan2
- IQCH | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 77/247 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769242387, COSV60049680; called by muse, mutect2, varscan2
- IQGAP3 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs371514554; called by muse, mutect2, varscan2
- IQSEC1 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs139752173; called by muse, mutect2, varscan2
- IRAK2 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141312230; called by muse, mutect2, varscan2
- IRX1 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.339); catalogued as COSV57358951; called by muse, mutect2, varscan2
- ITGA3 | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1362794303, COSV50308519; called by muse, mutect2, varscan2
- ITGAD | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs148236672; called by muse, mutect2, varscan2
- ITGAL | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs369554955, COSV63321145; called by muse, mutect2, varscan2
- ITK | c.1153A>G p.K385E | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as rs767083015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITSN1 | c.2567+1G>A p.X856_splice | Splice Site (SNP) | VAF 30/112 reads (27%) | catalogued as rs758301777, COSV101180612; called by muse, mutect2, varscan2
- IZUMO1 | c.312C>T p.G104= | Splice Region (SNP) | VAF 29/93 reads (31%) | catalogued as rs781599576, COSV55804050; called by muse, mutect2
- JAG2 | c.3623C>T p.S1208L | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1225312355; called by muse, mutect2, varscan2
- JAKMIP3 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 81/255 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs1396794303, COSV53822447, COSV53827987; called by muse, mutect2, varscan2
- JMJD6 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.387); catalogued as rs377582812; called by muse, mutect2, varscan2
- KANSL2 | c.973+1G>A p.X325_splice | Splice Site (SNP) | VAF 23/69 reads (33%) | catalogued as rs1362978715, COSV63480225; called by muse, mutect2, varscan2
- KAT2A | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs377593132; called by muse, mutect2, varscan2
- KCNA4 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs775798928, COSV60250783; called by muse, mutect2, varscan2
- KCNB2 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV73049336; called by muse, mutect2, varscan2
- KCNH1 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 106/200 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs897024131; called by muse, mutect2, varscan2
- KCNH5 | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 83/332 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1346595307, COSV59777205; called by muse, mutect2, varscan2
- KCNJ4 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs760057677, COSV57858241; called by muse, mutect2, varscan2
- KCNJ8 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as rs933438680; called by muse, mutect2, varscan2
- KCNK18 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs139101102; called by muse, mutect2, varscan2
- KCNN3 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs1453830866, COSV55227079; called by muse, mutect2, varscan2
- KCNV2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 92/327 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.105); catalogued as rs766443513, COSV66056097; called by muse, mutect2, varscan2
- KCTD11 | c.466G>A p.V156I (on ENST00000333751 / NM_001363642.1; = p.V117I on NM_001002914.2) | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs754017618; called by muse, mutect2, varscan2
- KDM4C | c.2608G>A p.V870M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs767764034; called by muse, mutect2, varscan2
- KEAP1 | c.23G>A p.S8N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.483); catalogued as rs746950247; called by muse, mutect2, varscan2
- KHDRBS1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1354857143; called by muse, mutect2, varscan2
- KIAA0100 | c.5464C>T p.R1822W | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762433757, COSV66492448; called by muse, mutect2, varscan2
- KIAA0930 | c.253C>T p.R85W (on ENST00000336156 / NM_001009880.2; = p.R90W on NM_015264.2) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as rs1296579119; called by muse, mutect2, varscan2
- KIAA1549 | c.4932G>A p.S1644= | Splice Region (SNP) | VAF 12/49 reads (24%) | catalogued as rs764841633; called by muse, mutect2, varscan2
- KIAA1549 | c.1919C>T p.S640L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1413532699; called by muse, mutect2, varscan2
- KIDINS220 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 79/317 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.643); catalogued as rs572569622, COSV99876006; called by muse, mutect2, varscan2
- KIF26A | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1253740821; called by muse, mutect2, varscan2
- KIF2A | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs1007319532; called by muse, mutect2, varscan2
- KIF2B | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1275391820, COSV52132549, COSV52134497; called by muse, mutect2, varscan2
- KLC2 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.846); catalogued as rs1312987213, COSV57581450; called by muse, mutect2, varscan2
- KLF2 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as rs758601723, COSV99934249; called by muse, mutect2, varscan2
- KLF7 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs927327960, COSV58745442; called by muse, mutect2, varscan2
- KLHDC7A | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1319456377, COSV68769034; called by muse, mutect2, varscan2
- KLHL13 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.731); catalogued as rs751065887, COSV53250349; called by muse, mutect2, varscan2
- KLHL25 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.312); catalogued as rs372508532, COSV100563680; called by muse, mutect2, varscan2
- KLHL6 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV58067455; called by muse, mutect2
- KLK11 | c.770C>T p.A257V (on ENST00000594768 / NM_144947.3; = p.A225V on NM_006853.3) | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs759848513, COSV100011003; called by muse, mutect2, varscan2
- KMT2D | c.11221C>T p.Q3741* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV56472480; called by muse, mutect2, varscan2
- KMT2D | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs771025627, COSV56422045; called by muse, mutect2, varscan2
- KNOP1 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs757928834, COSV54926546; called by muse, mutect2, varscan2
- KPNA1 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 121/307 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as rs764619803; called by muse, mutect2, varscan2
- KPNA7 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs752758269; called by muse, mutect2, varscan2
- KRT78 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs992640385; called by muse, mutect2, varscan2
- KRT82 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149651491; called by muse, mutect2, varscan2
- KRT85 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.409); catalogued as rs201610119, COSV57736761; called by muse, varscan2
- KSR1 | c.2588G>A p.R863Q (on ENST00000644974 / NM_001367810.1; = p.R748Q on NM_014238.2) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1055954960; called by muse, mutect2, varscan2
- KSR2 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs748664847, COSV60372983; called by muse, mutect2, varscan2
- LAMB2 | c.5060C>T p.T1687M | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as rs747774667, COSV59736537; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 50/159 reads (31%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LBR | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 202/886 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs532068854; called by muse, varscan2
- LCT | c.1789G>A p.V597M | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1465020980; called by muse, mutect2, varscan2
- LGALS3BP | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs867731601; called by muse, mutect2, varscan2
- LGR4 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.069); catalogued as rs769421305, COSV101004192; called by muse, mutect2, varscan2
- LHFPL5 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 92/467 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.441); catalogued as rs750723647; called by muse, mutect2, varscan2
- LIN9 | c.1081C>T p.R361W (on ENST00000366808 / NM_001270410.2; = p.R306W on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 139/526 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60243786; called by muse, mutect2, varscan2
- LIPN | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 104/187 reads (56%) | catalogued as rs1241053812, COSV68384082, COSV68384297; called by muse, mutect2, varscan2
- LMBRD1 | c.866G>A p.R289H (on ENST00000649011; = p.R267H on NM_018368.4) | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs140874824; called by muse, mutect2, varscan2
- LMF1 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555435528, COSV99234479, COSV99235138; called by muse, mutect2, varscan2
- LMF1 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs773491556, COSV51896479; called by muse, mutect2, varscan2
- LMF2 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); catalogued as rs769840454; called by muse, mutect2, varscan2
- LMO7 | c.2842G>A p.A948T (on ENST00000357063; = p.A629T on NM_005358.5) | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs370412695; called by muse, mutect2, varscan2
- LMO7 | c.4417C>T p.R1473* (on ENST00000357063; = p.R1154* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 43/160 reads (27%) | catalogued as rs1391756760, COSV58544400; called by muse, mutect2, varscan2
- LPAR3 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1430003017; called by muse, mutect2, varscan2
- LPP | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs770028872, COSV57089464; called by muse, mutect2, varscan2
- LRGUK | c.116A>G p.Q39R | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs757168128; called by muse, mutect2, varscan2
- LRP1B | c.12028G>A p.V4010I | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs267598907, COSV67289120; called by muse, mutect2, varscan2
- LRP2 | c.4988G>A p.R1663H | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs200766881, COSV55541498; called by muse, mutect2, varscan2
- LRRC47 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377537674; called by muse, mutect2, varscan2
- LRRC74B | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as rs1375565081; called by muse, mutect2, varscan2
- LRRTM1 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.817); catalogued as COSV54438776; called by muse, mutect2, varscan2
- LSM14A | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1289532889; called by muse, mutect2, varscan2
- LSS | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs200708561; called by muse, mutect2, varscan2
- LTB4R2 | c.584G>T p.R195M (on ENST00000528054; = p.R164M on NM_019839.5) | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.277); catalogued as COSV99351061; called by muse, mutect2, varscan2
- LTN1 | c.1418C>T p.T473M | Missense Mutation (SNP) | VAF 86/314 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs752825301; called by muse, mutect2, varscan2
- LTN1 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1477853095; called by muse, mutect2, varscan2
- LUM | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747899454, COSV57127852; called by muse, mutect2, varscan2
- LVRN | c.2372C>T p.A791V | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as rs775370416, COSV63497774; called by muse, mutect2, varscan2
- LYG1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs767349813; called by muse, varscan2
- LYPD8 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs781798219; called by muse, mutect2, varscan2
- LYPLA2 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs375628913; called by muse, mutect2, varscan2
- LZTS3 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.565); catalogued as rs773374471, COSV61279479; called by muse, varscan2
- MAEA | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs765652453, COSV53262021; called by muse, mutect2, varscan2
- MAGI1 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as rs375653415; called by muse, mutect2, varscan2
- MAK | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 87/1042 reads (8%) | catalogued as COSV57568201; called by muse, mutect2
- MAP1A | c.7294G>T p.A2432S | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV55807086; called by muse, mutect2, varscan2
- MAP3K1 | c.1705G>A p.V569I | Missense Mutation (SNP) | VAF 121/389 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV68124341; called by muse, mutect2, varscan2
- MAP3K11 | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as rs1207383117, COSV100442332; called by muse, mutect2, varscan2
- MAP3K4 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs747759728, COSV100815001; called by muse, mutect2, varscan2
- MAPK7 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 94/264 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773156619; called by muse, mutect2, varscan2
- MAPRE3 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs1027026616, COSV51866686; called by muse, mutect2, varscan2
- MAST3 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 200/628 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs775704646; called by muse, mutect2, varscan2
- MATK | c.1154G>A p.R385Q (on ENST00000310132 / NM_139355.3; = p.R386Q on NM_002378.4) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs1041475245; called by muse, mutect2, varscan2
- MATK | c.955C>T p.R319W (on ENST00000310132 / NM_139355.3; = p.R320W on NM_002378.4) | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1007384778, COSV59555623; called by muse, mutect2, varscan2
- MAX | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as rs762084527, COSV52417123; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MBD6 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs756453796; called by muse, mutect2, varscan2
- MBNL2 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs1300870013, COSV59119344; called by muse, mutect2, varscan2
- MCC | c.1955C>T p.T652M | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs751790153, COSV56731024; called by muse, mutect2, varscan2
- MCM6 | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759630336, COSV51466107; called by muse, mutect2, varscan2
- MCM9 | c.1699C>T p.R567W | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs935422225; called by muse, mutect2
- MED16 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs144332170; called by muse, mutect2, varscan2
- MED24 | c.2680C>T p.R894W | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs142219986; called by muse, mutect2, varscan2
- MED24 | c.2135C>T p.T712M | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs145215690; called by muse, mutect2, varscan2
- MEGF6 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374440544; called by muse, varscan2
- MELK | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs200746617; called by muse, mutect2, varscan2
- MEMO1 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 67/231 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs1303988275, COSV54451031; called by muse, mutect2, varscan2
- METAP1D | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as rs751521756, COSV59929602; called by muse, mutect2, varscan2
- METTL22 | c.1107G>T p.K369N | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1164624102; called by muse, mutect2, varscan2
- METTL24 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs545654177, COSV58823487; called by muse, mutect2, varscan2
- MFN2 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 83/266 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs754683866, COSV52426366; called by muse, mutect2, varscan2
- MFSD2B | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773602625, COSV57855873; called by muse, mutect2, varscan2
- MGA | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 177/285 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs528733174, COSV99579728; called by muse, mutect2, varscan2
- MGAT1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | PolyPhen probably damaging (1); catalogued as rs769149714, COSV57135409; called by mutect2, varscan2
- MINK1 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.931); catalogued as rs751020945, COSV61788847; called by muse, mutect2, varscan2
- MKI67 | c.3727G>A p.A1243T | Missense Mutation (SNP) | VAF 94/414 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.344); catalogued as COSV64072393; called by muse, mutect2, varscan2
- MMD2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs747236601, COSV68661333; called by muse, mutect2, varscan2
- MMP24 | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770843975; called by muse, mutect2, varscan2
- MN1 | c.129del p.P45Lfs*8 | Frame Shift Del (DEL) | VAF 54/193 reads (28%) | catalogued as COSV56556167; called by mutect2, pindel, varscan2
- MOB3C | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs1557916438, COSV54718677; called by muse, mutect2, varscan2
- MOV10 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs963236566, COSV62491073; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as rs779880394, COSV100187112; called by muse, mutect2, varscan2
- MPRIP | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs372089723, COSV59053418, COSV59055691; called by muse, mutect2, varscan2
- MPZL1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 77/140 reads (55%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.629); catalogued as rs764835005; called by muse, mutect2, varscan2
- MRPL32 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 87/284 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs780282413, COSV56237828; called by muse, mutect2, varscan2
- MRTFA | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780892147, COSV62931415; called by muse, varscan2
- MSC | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 88/280 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs776388351; called by muse, mutect2, varscan2
- MTA1 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58755350; called by muse, mutect2, varscan2
- MTHFD1 | c.1927G>A p.A643T | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs765252643; called by muse, mutect2
- MTMR11 | c.1225C>T p.R409* (on ENST00000439741 / NM_001145862.2; = p.R337* on NM_181873.3) | Nonsense Mutation (SNP) | VAF 43/122 reads (35%) | catalogued as rs782759787, COSV54964566; called by muse, mutect2, varscan2
- MTNR1B | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.082); catalogued as rs777474311; called by muse, mutect2, varscan2
- MTR | c.3127G>A p.D1043N | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1227536905, COSV63966112; called by muse, mutect2, varscan2
- MUC13 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs142060793; called by muse, mutect2, varscan2
- MUC16 | c.37970A>G p.Y12657C | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.991); catalogued as rs767757881; called by muse, mutect2, varscan2
- MUC19 | c.424del p.Y142Mfs*99 | Frame Shift Del (DEL) | VAF 59/199 reads (30%) | catalogued as rs776041179; called by mutect2, pindel, varscan2
- MX2 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759310607; called by muse, mutect2, varscan2
- MXD3 | c.148dup p.Q50Pfs*15 | Frame Shift Ins (INS) | VAF 36/98 reads (37%) | catalogued as rs866699857; called by mutect2, varscan2
- MYB | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs750351406; called by muse, mutect2, varscan2
- MYBBP1A | c.2758G>A p.A920T | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs747847889, COSV54604371; called by muse, mutect2, varscan2
- MYBPC2 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs765476587, COSV63094943; called by muse, mutect2, varscan2
- MYBPC2 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as rs749460100, COSV63098114, COSV63098169; called by muse, mutect2, varscan2
- MYH10 | c.3227C>T p.A1076V | Missense Mutation (SNP) | VAF 92/306 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.407); catalogued as rs150206681; called by muse, mutect2, varscan2
- MYH11 | c.5329C>T p.R1777C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1441546016, COSV55542564, COSV55564570; called by muse, mutect2, varscan2
- MYH11 | c.5197C>T p.R1733C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1335030890, COSV55564578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH11 | c.2729G>A p.R910Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs146404868, COSV55543155, COSV55564586; called by muse, mutect2, varscan2
- MYH14 | c.3175C>T p.R1059C | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs1158319494, COSV99222108; called by muse, mutect2, varscan2
- MYH14 | c.3851G>A p.R1284Q | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as rs201181045, COSV51813286; called by muse, mutect2, varscan2
- MYH6 | c.5754G>T p.Q1918H | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100198153; called by muse, mutect2, varscan2
- MYLK | c.2608C>T p.R870* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as rs865903260; called by muse, mutect2, varscan2
- NAPEPLD | c.249G>A p.W83* | Nonsense Mutation (SNP) | VAF 108/374 reads (29%) | catalogued as rs1469634083; called by muse, varscan2
- NAPG | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs916066691, COSV59796723; called by muse, mutect2, varscan2
- NAV3 | c.3880G>A p.G1294S | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.999); catalogued as rs762424798, COSV57091499, COSV99892305; called by muse, mutect2, varscan2
- NAXD | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs763387141; called by muse, mutect2, varscan2
- NBEAL2 | c.4355C>T p.S1452L | Missense Mutation (SNP) | VAF 133/364 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.044); catalogued as rs755590544, COSV52760351, COSV99434396; called by muse, mutect2, varscan2
- NCAM1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.151); catalogued as COSV57515835; called by muse, mutect2, varscan2
- NCAPG2 | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51986524; called by muse, mutect2, varscan2
- NCAPG2 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753719449; called by muse, mutect2, varscan2
- NCOA4 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs782564433; called by muse, mutect2, varscan2
- NEB | c.15781G>A p.A5261T | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV51446144; called by muse, mutect2, varscan2
- NEIL1 | c.743G>A p.S248N | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1169742827; called by muse, mutect2, varscan2
- NELL1 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1392440764, COSV100117576, COSV54255390; called by muse, mutect2, varscan2
- NFASC | c.361C>T p.R121C (on ENST00000339876 / NM_001378329.1; = p.R115C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1001294514, COSV58358205; called by muse, mutect2, varscan2
- NFE2 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs746400479; called by muse, mutect2, varscan2
- NFKBIB | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as rs575750550; called by muse, mutect2, varscan2
- NFS1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs148047173; called by muse, mutect2, varscan2
- NGDN | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs763908852, COSV68142812; called by muse, mutect2, varscan2
- NIBAN2 | c.315+1G>A p.X105_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100964937; called by muse, mutect2, varscan2
- NIBAN3 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.04); catalogued as COSV56311093; called by muse, mutect2, varscan2
- NKD2 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs375289481, COSV56890246; called by muse, mutect2, varscan2
- NKRF | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 46/66 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs949255431; called by muse, mutect2, varscan2
- NKX2-1 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV61389830, COSV61389878; called by muse, varscan2
- NLRC5 | c.5149del p.H1717Ifs*29 | Frame Shift Del (DEL) | VAF 65/220 reads (30%) | catalogued as COSV52661262; called by mutect2, pindel, varscan2
- NLRP14 | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs776547306, COSV55066379; called by muse, mutect2, varscan2
- NLRP5 | c.1397A>G p.D466G | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs913775836, COSV66766634; called by muse, mutect2, varscan2
- NLRP7 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs1339008404, COSV100053507, COSV60176547; called by muse, mutect2, varscan2
- NMT1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as rs1415777939, COSV51963034; called by muse, mutect2, varscan2
- NOD2 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.674); catalogued as rs755554858; called by muse, mutect2, varscan2
- NOL4L | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 86/291 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs777528566, COSV100675631; called by muse, mutect2, varscan2
- NOLC1 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs1023578646, COSV64179943; called by muse, mutect2, varscan2
- NOP53 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs774393641, COSV54407223; called by muse, mutect2, varscan2
- NOTCH3 | c.5102C>T p.A1701V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as COSV54637875; called by muse, mutect2, varscan2
- NPAP1 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.924); catalogued as rs1195117251, COSV61508177, COSV61513035; called by muse, mutect2, varscan2
- NPAS2 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs778685112; called by muse, mutect2, varscan2
- NPEPL1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs777053585; called by muse, mutect2, varscan2
- NPHS1 | c.3368G>A p.R1123Q | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs774500707, COSV62287760, COSV62288416; called by muse, mutect2, varscan2
- NPHS1 | c.2468C>T p.A823V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.793); catalogued as rs771078444, COSV62288508; called by muse, mutect2, varscan2
- NPR1 | c.2909G>A p.R970H | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs144189754, COSV64118032; called by muse, mutect2, varscan2
- NPR2 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 112/322 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs766889818, COSV61311172; called by muse, mutect2, varscan2
- NPR2 | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61314056, COSV99047869; called by muse, mutect2, varscan2
- NR1D1 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52840339; called by muse, mutect2, varscan2
- NRG1 | c.749G>A p.C250Y (on ENST00000405005 / NM_013964.5; = p.C255Y on NM_013956.5) | Missense Mutation (SNP) | VAF 73/247 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55171283; called by muse, varscan2
- NRG2 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 70/263 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs749464757, COSV56833457, COSV56834647; called by muse, mutect2, varscan2
- NSD3 | c.2116-1G>A p.X706_splice | Splice Site (SNP) | VAF 23/61 reads (38%) | catalogued as COSV57621182; called by muse, mutect2, varscan2
- NSF | c.1917G>T p.K639N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56576193; called by muse, mutect2, varscan2
- NSMAF | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs367758314; called by muse, mutect2, varscan2
- NT5C1B | c.763G>A p.A255T (on ENST00000359846 / NM_001199086.2; = p.A195T on NM_033253.4) | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs1313395885; called by muse, mutect2, varscan2
- NT5C3B | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | catalogued as COSV53172651; called by muse, mutect2, varscan2
- NTN4 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs371661550, COSV59218112; called by muse, mutect2, varscan2
- NUAK1 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs139582229, COSV54603574; called by muse, mutect2, varscan2
- NUB1 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs373576077; called by muse, mutect2, varscan2
- NUB1 | c.1784C>T p.A595V (on ENST00000568733 / NM_001243351.1; = p.A581V on NM_016118.4) | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.804); catalogued as rs868105409; called by muse, mutect2, varscan2
- NUDT1 | c.373C>T p.R125C (on ENST00000397048 / NM_198952.1; = p.R102C on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as rs747651511; called by muse, mutect2, varscan2
- NUDT16L1 | c.442T>C p.Y148H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1438313599; called by muse, mutect2, varscan2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- NUP133 | c.2327C>T p.T776M | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); catalogued as rs770096040, COSV99772512; called by muse, mutect2, varscan2
- NUP210 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs758003408; called by muse, mutect2, varscan2
- NUP98 | c.4153C>A p.L1385I (on ENST00000359171 / NM_001365126.1; = p.L1368I on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.492); catalogued as COSV100261484; called by muse, mutect2, varscan2
- NXF1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs778851087; called by muse, varscan2
- NYAP2 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1045254100, COSV55998277; called by muse, mutect2, varscan2
- OBSL1 | c.2107C>T p.Q703* | Nonsense Mutation (SNP) | VAF 49/137 reads (36%) | catalogued as COSV54727708; called by muse, mutect2, varscan2
- OLR1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.388); catalogued as rs769789426, COSV100376361; called by muse, mutect2, varscan2
- OR1N2 | c.68G>A p.W23* | Nonsense Mutation (SNP) | VAF 50/203 reads (25%) | catalogued as rs766526272; called by muse, mutect2
- OR2L5 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 121/236 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs756291968, COSV62365393; called by muse, mutect2, varscan2
- OR2W1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 124/483 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs896592244, COSV65851468; called by muse, mutect2, varscan2
- OR4K15 | c.338G>A p.R113H (on ENST00000305051; = p.R89H on NM_001005486.1) | Missense Mutation (SNP) | VAF 21/268 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139377821, COSV100520989; called by muse, mutect2
- OR51M1 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV60785304; called by muse, mutect2, varscan2
- OR51V1 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as rs182727082, COSV58314852; called by muse, mutect2, varscan2
- OR52H1 | c.604T>C p.F202L (on ENST00000322653; = p.F208L on NM_001005289.1) | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.246); catalogued as COSV59505082; called by muse, mutect2, varscan2
- OR52R1 | c.858A>G p.I286M | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV100617770; called by muse, mutect2, varscan2
- OR5C1 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV65456011; called by muse, mutect2, varscan2
- OR8H1 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57293753; called by muse, mutect2, varscan2
- OSBPL8 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 79/261 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs200132037; called by muse, mutect2, varscan2
- OTOF | c.3695G>A p.R1232Q (on ENST00000272371 / NM_194248.3; = p.R485Q on NM_004802.4) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.56); catalogued as rs371588016, COSV99717225; called by muse, mutect2, varscan2
- OTOP2 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs761229321; called by muse, mutect2, varscan2
- OXER1 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.047); catalogued as rs140987475; called by muse, mutect2, varscan2
- P2RY2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as COSV60778149; called by muse, mutect2, varscan2
- P2RY2 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs148967472, COSV100232929; called by muse, mutect2
- P2RY4 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as rs778002771; called by muse, mutect2, varscan2
- PABPC4L | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 101/332 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.719); catalogued as rs369585514, COSV99081464; called by muse, mutect2, varscan2
- PACSIN2 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1480334213, COSV54319085; called by muse, mutect2, varscan2
- PAK6 | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1169657232; called by muse, mutect2, varscan2
- PAQR8 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746307084; called by muse, varscan2
- PAQR9 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.308); catalogued as rs772961205, COSV61418565; called by muse, mutect2, varscan2
- PARK7 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs145727915; called by muse, mutect2, varscan2
- PARN | c.178-8T>C | Splice Region (SNP) | VAF 23/69 reads (33%) | catalogued as COSV58369586; called by muse, mutect2, varscan2
- PARP1 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377397890; called by muse, mutect2, varscan2
- PBX3 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 44/148 reads (30%) | catalogued as rs866234715, COSV60734857; called by muse, mutect2, varscan2
- PC | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs119103242, CM092838, COSV58921076; called by muse, varscan2
- PCDHA8 | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs564409198, COSV100969336; called by muse, mutect2, varscan2
- PCDHAC2 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.646); catalogued as rs781929483; called by muse, mutect2, varscan2
- PCDHGA12 | c.1904G>T p.R635I | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.457); catalogued as COSV99343168; called by muse, mutect2, varscan2
- PCDHGA2 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.358); catalogued as rs1355486436, COSV53928692; called by muse, mutect2, varscan2
- PCLO | c.14053G>A p.D4685N | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs369280378; called by muse, mutect2, varscan2
- PCNT | c.4201G>A p.E1401K | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs776308749; called by muse, mutect2, varscan2
- PCSK2 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs542607464, COSV52726393; called by muse, mutect2, varscan2
- PCYT1B | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 80/122 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV63264472; called by muse, mutect2, varscan2
- PDGFA | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs145010817; called by muse, mutect2, varscan2
- PDIA2 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as rs1178492539, COSV99250201; called by muse, mutect2, varscan2
- PDZD2 | c.2872C>T p.R958C | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359009626; called by muse, mutect2, varscan2
- PDZD2 | c.7204G>A p.E2402K | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1479682163, COSV56852172; called by muse, mutect2, varscan2
- PELI3 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.422); catalogued as rs756980058; called by muse, mutect2, varscan2
- PELI3 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as rs755175557, COSV100291901; called by muse, mutect2, varscan2
- PEX11G | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs761081474; called by muse, mutect2, varscan2
- PGLYRP4 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs200799317; called by muse, mutect2, varscan2
- PHC1 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.365); catalogued as COSV70418137; called by muse, mutect2
- PHF12 | c.2111C>T p.T704M | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs139914566; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 29/76 reads (38%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF2 | c.2764C>T p.R922C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777717056, COSV63683014; called by muse, mutect2, varscan2
- PHGR1 | c.175del p.H59Tfs*49 | Frame Shift Del (DEL) | VAF 23/52 reads (44%) | catalogued as rs748850271; called by pindel, varscan2
- PHRF1 | c.4891C>T p.R1631C (on ENST00000264555 / NM_001286581.2; = p.R1630C on NM_020901.4) | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs756256706, COSV52760392; called by muse, mutect2, varscan2
- PIEZO1 | c.6803C>T p.A2268V | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs777875339, COSV56333471; called by muse, mutect2, varscan2
- PIK3C2B | c.2414G>A p.R805H | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as rs780535663; called by muse, mutect2, varscan2
- PKD1 | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs773994484, COSV99238791; called by muse, mutect2, varscan2
- PKD2 | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 77/277 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as rs529945469; called by muse, mutect2, varscan2
- PKD2 | c.2461G>A p.G821R | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52938517; called by muse, mutect2, varscan2
- PKD2L1 | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs556892956; called by muse, mutect2, varscan2
- PKHD1 | c.5723T>C p.I1908T | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as CM054806; called by muse, mutect2, varscan2
- PKN2 | c.2881C>T p.R961* | Nonsense Mutation (SNP) | VAF 28/115 reads (24%) | catalogued as rs1314658560, COSV65142839; called by muse, mutect2, varscan2
- PLCH1 | c.2509C>T p.R837W (on ENST00000340059 / NM_001130960.2; = p.R849W on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251158811, COSV100396755; called by muse, mutect2, varscan2
- PLEC | c.10202C>T p.A3401V (on ENST00000322810 / NM_201380.4; = p.A3291V on NM_000445.5) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs200413602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHD1 | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs556157688, COSV59446475; called by muse, mutect2, varscan2
- PLEKHG2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1019326084; called by muse, mutect2, varscan2
- PLEKHG4 | c.2315G>A p.R772H | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765749525, COSV58571329; called by muse, mutect2, varscan2
- PLEKHM2 | c.3028C>T p.R1010C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs781466914, COSV53816324; called by muse, mutect2, varscan2
- PLEKHM3 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.355); catalogued as rs760143757, COSV66816239; called by muse, mutect2, varscan2
- PLIN3 | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.269); catalogued as rs769468220, COSV55734101, COSV55734286; called by muse, mutect2, varscan2
- PLXNA1 | c.3313C>T p.R1105C | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.631); catalogued as rs376747849; called by muse, mutect2, varscan2
- PLXNB1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs760971221; called by muse, mutect2, varscan2
- PLXNB3 | c.4436G>A p.R1479Q | Missense Mutation (SNP) | VAF 62/84 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100737313; called by muse, mutect2, varscan2
- PLXNB3 | c.4963del p.V1655Cfs*7 | Frame Shift Del (DEL) | VAF 26/40 reads (65%) | catalogued as rs782076287; called by mutect2, varscan2
- PMS2 | c.2266G>A p.D756N | Missense Mutation (SNP) | VAF 120/695 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs762206330, COSV56220932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNMA8B | c.28T>G p.C10G | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV66537420; called by muse, mutect2, varscan2
- PNPLA7 | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs2298171; called by muse, mutect2, varscan2
- POGZ | c.632C>A p.P211H | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.201); catalogued as COSV55040274; called by muse, mutect2, varscan2
- POLDIP3 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs113566870, COSV52808891; called by muse, mutect2, varscan2
- POLR2E | c.57+6C>T | Splice Region (SNP) | VAF 91/247 reads (37%) | catalogued as rs377537583; called by muse, mutect2, varscan2
- POLRMT | c.2681C>T p.T894M | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs988161909, COSV52116650, COSV99241527; called by muse, mutect2, varscan2
- POP1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs150132872; called by muse, mutect2, varscan2
- POSTN | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 75/246 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.751); catalogued as rs117790304; called by muse, mutect2, varscan2
- POSTN | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 65/190 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142297717; called by muse, mutect2, varscan2
- PPM1D | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.045); catalogued as COSV59957014; called by muse, varscan2
- PPM1H | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.187); catalogued as rs540042623, COSV57377634, COSV57378235; called by muse, mutect2, varscan2
- PPME1 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 91/279 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs79972734; called by muse, mutect2, varscan2
- PPME1 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs367984063; called by muse, mutect2, varscan2
- PPP1R2 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 23/354 reads (6%) | catalogued as COSV100113416; called by muse, mutect2
- PPP1R3B | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs368157445; called by muse, mutect2, varscan2
- PPRC1 | c.4397G>A p.R1466Q | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs749450563, COSV104375852; called by muse, mutect2, varscan2
- PRAG1 | c.3052G>A p.G1018S | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as rs755907827, COSV58164631; called by muse, mutect2, varscan2
- PRAMEF14 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 99/367 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as rs199937476; called by muse, mutect2, varscan2
- PRAMEF20 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs962195338; called by muse, mutect2, varscan2
- PRDM2 | c.5048G>A p.R1683H | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs754582779, COSV52443129; called by muse, mutect2, varscan2
- PRDM9 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 48/141 reads (34%) | catalogued as COSV57006297, COSV57011793; called by muse, mutect2, varscan2
- PREX1 | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.075); catalogued as rs749750409, COSV64254726; called by muse, mutect2, varscan2
- PRKACG | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV55261803; called by muse, mutect2, varscan2
- PRKCB | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs563116744, COSV57805302; called by muse, mutect2, varscan2
- PRMT6 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as rs926157359; called by muse, mutect2, varscan2
- PROC | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs886054848, COSV52167530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PROCA1 | c.934C>T p.R312W (on ENST00000439862 / NM_001366301.1; = p.R284W on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs201634767; called by muse, mutect2, varscan2
- PROKR1 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV58136870; called by muse, mutect2, varscan2
- PRPSAP1 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100221798; called by muse, mutect2, varscan2
- PSD4 | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149806578, COSV55524945; called by muse, mutect2, varscan2
- PSMD11 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs201116985; called by muse, mutect2, varscan2
- PSME3 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs777707701; called by muse, mutect2, varscan2
- PTBP1 | c.1129G>A p.A377T (on ENST00000349038 / NM_031991.4; = p.A403T on NM_002819.5) | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV62458956; called by muse, mutect2, varscan2
1,492 further variants in this file (791 protein-altering or splice-affecting, 575 silent, 126 other) are not listed here.
